Somatic mutation profile of tumor specimen MBCProject_0289_T1_WES (aliquot MBCProject_0289_T1_WES_1) from CMI case MBCProject_0289, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 32.4 years (11,849 days).
Specimen MBCProject_0289_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b08e983-2bcf-4e0b-bbc9-e01c4f2b1cab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0289_SALIVA (Saliva), aliquot MBCProject_0289_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2abcce9e-de53-4524-8540-819097b7b610

The open-access MAF lists 38 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, 3'UTR 3, Splice Site 2, Nonsense Mutation 1, 5'UTR 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 39/181 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C9orf24 | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs756236763; called by muse, mutect2, varscan2
- DPP9 | c.990C>T p.I330= (on ENST00000598800; = p.I359= on NM_139159.5) | Splice Region (SNP) | VAF 54/171 reads (32%) | catalogued as rs759316387, COSV53594237; called by muse, mutect2, varscan2
- EGR2 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99654017; called by muse, mutect2, varscan2
- FN3K | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 71/1174 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.047); catalogued as rs1432118719; called by muse, mutect2
- KRT34 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 95/286 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs143564749; called by muse, mutect2, varscan2
- MYO18A | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as rs755153578, COSV62863445; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC22A2 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774203224; called by muse, mutect2, varscan2
- SLC22A3 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.233); catalogued as COSV99279504; called by muse, mutect2
- ADAMTSL1 | c.3473G>A p.R1158Q | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ALAS2 | c.1487A>G p.K496R | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.029); called by muse, mutect2
- BCL2A1 | c.433G>T p.V145L | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1S | c.517+1G>A p.X173_splice | Splice Site (SNP) | VAF 81/290 reads (28%) | called by muse, mutect2, varscan2
- COL11A1 | c.2816C>T p.P939L | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- COL26A1 | c.1291C>A p.Q431K (on ENST00000313669 / NM_001278563.3; = p.Q429K on NM_133457.4) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2
- EPPK1 | c.4403C>A p.S1468* | Nonsense Mutation (SNP) | VAF 22/510 reads (4%) | called by muse, mutect2
- FN3K | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 50/519 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- HTR3C | c.1294C>T p.L432F | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.851); called by muse, mutect2
- NF1 | c.5951del p.N1984Mfs*28 (on ENST00000358273 / NM_001042492.3; = p.N1963Mfs*28 on NM_000267.3) | Frame Shift Del (DEL) | VAF 43/145 reads (30%) | called by mutect2, pindel, varscan2
- PLXNA4 | c.3956C>A p.T1319N | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RGPD3 | c.5032G>C p.A1678P | Missense Mutation (SNP) | VAF 110/396 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RIPK2 | c.174-5_175delinsTTTTTTT p.X58_splice | Splice Site (ONP) | VAF 12/99 reads (12%) | called by muse*, pindel
- SCAF4 | c.3183A>T p.R1061S | Missense Mutation (SNP) | VAF 92/385 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- THOC2 | c.1670C>G p.T557S | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.92); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- TPCN1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- WRN | c.1846G>A p.A616T | Missense Mutation (SNP) | VAF 62/472 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- APPL2 | c.1914A>G p.G638= | Silent (SNP) | VAF 41/176 reads (23%) | called by muse, mutect2
- C1QL4 | c.129C>T p.D43= | Silent (SNP) | VAF 9/36 reads (25%) | called by mutect2, varscan2
- CDH22 | c.1239C>T p.V413= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV100953004, COSV64836522; called by muse, mutect2
- CGB7 | c.429C>T p.A143= | Silent (SNP) | VAF 30/172 reads (17%) | called by muse, mutect2, varscan2
- JAK3 | c.2142G>A p.T714= | Silent (SNP) | VAF 66/255 reads (26%) | catalogued as rs1473714442, COSV101512885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLG | c.1474C>T p.L492= | Silent (SNP) | VAF 195/678 reads (29%) | called by muse, mutect2, varscan2
- TACC1 | c.930G>A p.G310= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as rs752420787; called by muse, mutect2, varscan2
- VWF | c.1311C>T p.D437= | Silent (SNP) | VAF 146/556 reads (26%) | catalogued as rs374722386; called by muse, mutect2, varscan2
- BAD | c.*47C>A | 3'UTR (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- CELF3 | c.*287_*314del | 3'UTR (DEL) | VAF 32/104 reads (31%) | called by pindel, varscan2
- SPI1 | c.-37C>T | 5'UTR (SNP) | VAF 45/164 reads (27%) | catalogued as rs768539901, COSV57043979; called by muse, mutect2, varscan2
- XBP1 | c.*113_*114del | 3'UTR (DEL) | VAF 66/212 reads (31%) | called by pindel, varscan2
